Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UY-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of uterine cervix":

- Moderately differentiated invasive squamous cell carcinoma.
- Vascular invasion not detected.

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C53.9
JW 3/7/14

Source: NCI Genomic Data Commons file 5189f35a-5f53-4e30-8e5d-c3079aaf4889 (TCGA-VS-A9UY.DDC2DC1F-C4E3-4F51-9F0C-3EE90A7C4819.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).